Somatic mutation profile of tumor specimen C3L-03743-01 (aliquot CPT0264150009) from CPTAC case C3L-03743, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.3 years (26,051 days).
Specimen C3L-03743-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a10f04d-3eb6-497f-8650-74f5f9ee3d61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03743-31 (Blood Derived Normal), aliquot CPT0265780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beb855bc-d92d-42b7-813e-fc88c7c6bfeb

The open-access MAF lists 90 somatic variants for this specimen: 57 protein-altering or splice-affecting, 26 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 26, Intron 6, Nonsense Mutation 3, Splice Site 2, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 133/571 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 175/954 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 69/480 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782567931, COSV54351680; called by muse, mutect2, varscan2
- AOX1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs368293055, COSV65981353; called by muse, mutect2
- ARHGEF17 | c.5027C>T p.T1676M | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs989455757, COSV55234239; called by muse, mutect2, varscan2
- CACNB4 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99138428; called by muse, mutect2, varscan2
- CARNS1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV57129983; called by muse, mutect2
- CPEB2 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 96/572 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as rs781349176; called by muse, varscan2
- CSF2RA | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 71/666 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs759083963, COSV62624542; called by muse, mutect2
- EFHD1 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 69/414 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs748253697; called by muse, mutect2, varscan2
- FAM110B | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs755553412, COSV64064194; called by muse, mutect2
- GAB2 | c.1499G>A p.R500Q (on ENST00000361507 / NM_080491.3; = p.R462Q on NM_012296.3) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs370982595, COSV60867265; called by muse, mutect2, varscan2
- GNAS | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 158/914 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.284); catalogued as rs745875776, COSV58331713; called by muse, mutect2, varscan2
- GREB1L | c.3806G>A p.R1269Q | Missense Mutation (SNP) | VAF 43/659 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1176278321; called by muse, mutect2
- KMT2C | c.11357C>T p.S3786L | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs1465317935, COSV51521702; called by muse, mutect2, varscan2
- KRT19 | c.179_190del p.A60_G63del | In Frame Del (DEL) | VAF 102/816 reads (13%) | catalogued as rs781617871; called by mutect2, pindel
- MIB2 | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1557624624; called by muse, varscan2
- MMP15 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 38/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910557137; called by muse, mutect2
- MSC | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 102/648 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57697609; called by muse, mutect2, varscan2
- NLRC3 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 54/742 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.708); catalogued as rs750986719; called by muse, mutect2
- OPRL1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 56/568 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs147804138; called by muse, mutect2
- OR4C3 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1331267009, COSV60584197; called by muse, mutect2, varscan2
- OR52N1 | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 95/654 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100398654; called by muse, mutect2, varscan2
- PCDHA7 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 110/1308 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.536); catalogued as rs1554135300, COSV65341820; called by muse, mutect2
- PCDHB2 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 142/1409 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); catalogued as rs782442205; called by muse, mutect2, varscan2
- PGR | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 10/250 reads (4%) | catalogued as rs1315135533, COSV54796997; called by muse, mutect2
- PNMA3 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 50/718 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs782584119; called by muse, mutect2
- PRAMEF19 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 134/1633 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs753459941; called by muse, mutect2
- PREX1 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 68/570 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100906632; called by muse, mutect2, varscan2
- RLBP1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs139108078; called by muse, mutect2, varscan2
- RYR3 | c.12073G>A p.E4025K (on ENST00000389232; = p.E4026K on NM_001036.6) | Missense Mutation (SNP) | VAF 55/459 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs573502706, COSV66778841; called by muse, mutect2, varscan2
- SAMD9L | c.4571G>A p.R1524H | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs138088725, COSV59082085; called by muse, mutect2
- SGCZ | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372855106; called by muse, mutect2
- SSR4 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 44/630 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.723); catalogued as rs1156431337; called by muse, mutect2
- SYNE1 | c.23138G>A p.R7713H (on ENST00000367255 / NM_182961.4; = p.R7642H on NM_033071.3) | Missense Mutation (SNP) | VAF 59/453 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs750911961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFHX3 | c.10609G>A p.A3537T | Missense Mutation (SNP) | VAF 92/602 reads (15%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV51738205; called by muse, mutect2, varscan2
- ABCD2 | c.1274A>G p.N425S | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ACACA | c.2848A>G p.N950D | Missense Mutation (SNP) | VAF 81/457 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ADGRF3 | c.1804G>T p.A602S (on ENST00000311519 / NM_001145168.1; = p.A403S on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/673 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- AHCYL1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C10orf67 | c.1358T>A p.L453H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FIBP | c.288C>A p.Y96* | Nonsense Mutation (SNP) | VAF 41/560 reads (7%) | called by muse, mutect2
- FLAD1 | c.1117G>C p.G373R | Missense Mutation (SNP) | VAF 39/522 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2
- FRYL | c.7689+1G>A p.X2563_splice | Splice Site (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- HSPG2 | c.8488C>A p.R2830S | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.975); called by muse, mutect2
- IGFLR1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- IRF8 | c.530G>T p.W177L | Missense Mutation (SNP) | VAF 70/804 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- ITIH4 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF1A | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 104/730 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRIQ1 | c.2198C>A p.T733N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MEI1 | c.3427+4G>C | Splice Region (SNP) | VAF 24/396 reads (6%) | called by muse, mutect2
- NUP155 | c.1246+1G>T p.X416_splice (on ENST00000231498 / NM_153485.3; = p.X357_splice on NM_004298.4) | Splice Site (SNP) | VAF 47/377 reads (12%) | called by muse, mutect2, varscan2
- PIKFYVE | c.5055G>T p.E1685D | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- RECQL4 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLE3 | c.118dup p.Y40Lfs*27 | Frame Shift Ins (INS) | VAF 28/232 reads (12%) | called by mutect2, pindel, varscan2
- TMEM241 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF469 | c.6985G>A p.G2329S (on ENST00000437464; = p.G2357S on NM_001367624.2) | Missense Mutation (SNP) | VAF 44/492 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2
- ACP4 | c.1146T>C p.Y382= | Silent (SNP) | VAF 91/250 reads (36%) | catalogued as rs773944011; called by muse, mutect2, varscan2
- CLEC2L | c.492C>T p.D164= | Silent (SNP) | VAF 45/462 reads (10%) | catalogued as rs547876426, COSV70691354; called by muse, mutect2
- CST11 | c.300G>A p.T100= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as rs770430472, COSV65440441; called by muse, mutect2, varscan2
- CYP26A1 | c.1068C>T p.I356= | Silent (SNP) | VAF 30/199 reads (15%) | catalogued as rs771602770, COSV56418195; called by muse, mutect2, varscan2
- DMRT3 | c.192G>T p.R64= | Silent (SNP) | VAF 60/513 reads (12%) | called by muse, mutect2, varscan2
- EPHA10 | c.1620C>A p.A540= | Silent (SNP) | VAF 19/208 reads (9%) | catalogued as COSV57625053; called by muse, mutect2
- GHR | c.1452C>T p.I484= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as rs778616140, COSV50111829; called by muse, mutect2, varscan2
- HR | c.573C>T p.G191= | Silent (SNP) | VAF 126/616 reads (20%) | called by muse, mutect2, varscan2
- ITGBL1 | c.309C>G p.T103= | Silent (SNP) | VAF 65/328 reads (20%) | catalogued as rs1233163098; called by muse, mutect2, varscan2
- LGALS16 | c.384A>G p.R128= | Silent (SNP) | VAF 130/425 reads (31%) | called by muse, mutect2, varscan2
- MON2 | c.5070C>T p.V1690= | Silent (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- MTSS2 | c.1980C>T p.A660= | Silent (SNP) | VAF 56/769 reads (7%) | catalogued as rs568672711; called by muse, mutect2
- MUC2 | c.270C>T p.R90= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs368859604; called by muse, mutect2, varscan2
- MYH15 | c.4026C>A p.A1342= | Silent (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- OR14I1 | c.459C>T p.Y153= | Silent (SNP) | VAF 29/322 reads (9%) | catalogued as rs200035502; called by muse, mutect2
- PABPC1 | c.1443T>C p.R481= | Silent (SNP) | VAF 35/487 reads (7%) | called by muse, mutect2
- PCDH8 | c.387C>T p.N129= | Silent (SNP) | VAF 28/378 reads (7%) | catalogued as rs200833172; called by muse, mutect2
- PCDHAC1 | c.1659G>A p.P553= | Silent (SNP) | VAF 32/406 reads (8%) | catalogued as rs782615304, COSV53865940, COSV99167542; called by muse, mutect2
- PERM1 | c.1908G>A p.P636= | Silent (SNP) | VAF 31/261 reads (12%) | catalogued as rs759972334, COSV100378962; called by muse, mutect2, varscan2
- PRR12 | c.1701C>T p.V567= (on ENST00000615927; = p.V1388= on NM_020719.3) | Silent (SNP) | VAF 40/822 reads (5%) | catalogued as rs752042891, COSV69816723; called by muse, mutect2
- SLC12A9 | c.819C>T p.V273= | Silent (SNP) | VAF 48/677 reads (7%) | called by muse, mutect2
- SLC9A3 | c.1530C>T p.F510= | Silent (SNP) | VAF 20/310 reads (6%) | catalogued as rs369450763, COSV53800998; called by muse, mutect2
- TRPC3 | c.777C>T p.I259= (on ENST00000379645 / NM_001366479.2; = p.I186= on NM_003305.2) | Silent (SNP) | VAF 58/684 reads (8%) | catalogued as rs201449030, COSV53373268; called by muse, mutect2
- TRPM3 | c.1767G>A p.T589= (on ENST00000357533 / NM_001366142.2; = p.T422= on NM_020952.6) | Silent (SNP) | VAF 108/677 reads (16%) | catalogued as rs763892148; called by muse, mutect2, varscan2
- VWA1 | c.1191C>T p.T397= | Silent (SNP) | VAF 34/353 reads (10%) | catalogued as rs1215471794; called by muse, mutect2, varscan2
- WDR62 | c.1659C>A p.A553= | Silent (SNP) | VAF 97/1269 reads (8%) | called by muse, mutect2
- CDH13 | c.2135-29C>T | Intron (SNP) | VAF 28/388 reads (7%) | catalogued as rs747841131; called by muse, mutect2
- HLA-B | c.343+44C>G | Intron (SNP) | VAF 32/271 reads (12%) | catalogued as rs771261870; called by muse, mutect2, varscan2
- NODAL | c.891+14C>T | Intron (SNP) | VAF 19/276 reads (7%) | catalogued as rs780042490; called by muse, mutect2
- SCN2B | c.*48C>T | 3'UTR (SNP) | VAF 121/707 reads (17%) | catalogued as rs374338920; called by muse, mutect2, varscan2
- STEAP1B | c.706-18850G>A | Intron (SNP) | VAF 89/552 reads (16%) | called by muse, mutect2, varscan2
- TSHZ2 | c.41-67864dup | Intron (INS) | VAF 40/264 reads (15%) | called by mutect2, varscan2
- ZFAT | c.3362-313C>T | Intron (SNP) | VAF 69/366 reads (19%) | catalogued as rs1482926836; called by muse, mutect2, varscan2
